Somatic mutation profile of tumor specimen 0DRRTY from CCDI case PBCCKK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 18.4 years (6,716 days).
Specimen 0DRRTY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96b4dc8e-c737-4200-8d4c-de600cd36ce4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRRTQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c319185-a692-4c94-acc7-c2a3e4a12dfc

The open-access MAF lists 65 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 12, Intron 6, 3'UTR 4, Splice Region 2, Nonsense Mutation 2, Frame Shift Ins 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP1 | c.1954C>T p.R652W (on ENST00000304032 / NM_001037131.3; = p.R599W on NM_014914.5) | Missense Mutation (SNP) | VAF 324/1066 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1352142794, COSV58319538, COSV58327096; called by muse, mutect2, varscan2
- ATP10B | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 223/508 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.27); catalogued as rs763114091, COSV59144351, COSV59164448; called by muse, mutect2, varscan2
- FAT1 | c.3599C>G p.S1200* | Nonsense Mutation (SNP) | VAF 492/1214 reads (41%) | catalogued as COSV101499573; called by muse, mutect2, varscan2
- GABRG1 | c.224A>G p.Y75C | Missense Mutation (SNP) | VAF 341/813 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs945053713; called by muse, mutect2, varscan2
- GATA3 | c.435C>A p.H145Q | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.52); catalogued as COSV60515498; called by muse, mutect2
- HMCN1 | c.3524G>A p.R1175H | Missense Mutation (SNP) | VAF 66/1448 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs527332989, COSV54881305; ClinVar: uncertain significance; called by muse, mutect2
- METTL8 | c.329A>G p.E110G | Missense Mutation (SNP) | VAF 82/1256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766708496; called by muse, mutect2
- OPRK1 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 286/1057 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747994574, COSV55568008; called by muse, mutect2, varscan2
- RHOT2 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 198/287 reads (69%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs780282687, COSV53471943; called by muse, mutect2, varscan2
- RNASEH1 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 136/1430 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs765802659; called by muse, mutect2
- SLC27A3 | c.530G>A p.R177H (on ENST00000271857; = p.R49H on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/425 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs892817725; called by muse, mutect2, varscan2
- SOX18 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1185671333; called by muse, mutect2
- SUFU | c.515C>G p.S172* | Nonsense Mutation (SNP) | VAF 271/842 reads (32%) | catalogued as COSV64015322; called by muse, mutect2, varscan2
- UTP25 | c.1571G>T p.W524L | Missense Mutation (SNP) | VAF 296/806 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs373916005, COSV71965784; called by mutect2, varscan2
- CCDC151 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 218/950 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 43/1352 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- CDK15 | c.276G>A p.R92= (on ENST00000652192 / NM_001366386.2; = p.R41= on NM_139158.2) | Splice Region (SNP) | VAF 91/1590 reads (6%) | called by muse, mutect2
- CEP120 | c.1955A>G p.K652R | Missense Mutation (SNP) | VAF 501/1149 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CMAS | c.489A>T p.E163D | Missense Mutation (SNP) | VAF 116/1856 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2
- CORO2A | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 57/889 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CSMD3 | c.2339G>C p.G780A (on ENST00000297405 / NM_001363185.1; = p.G676A on NM_052900.3) | Missense Mutation (SNP) | VAF 688/3208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTNNAL1 | c.242G>T p.R81I | Missense Mutation (SNP) | VAF 362/1050 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by mutect2, varscan2
- CYP1B1 | c.353C>A p.P118Q | Missense Mutation (SNP) | VAF 82/1066 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DENND5B | c.2841G>T p.K947N | Missense Mutation (SNP) | VAF 106/1579 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DIAPH1 | c.691A>G p.I231V | Missense Mutation (SNP) | VAF 40/956 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- EDIL3 | c.59T>A p.F20Y | Missense Mutation (SNP) | VAF 199/592 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSIP2 | c.18403dup p.C6135Lfs*13 | Frame Shift Ins (INS) | VAF 335/1164 reads (29%) | called by mutect2, pindel, varscan2
- IFIT1B | c.221G>T p.S74I | Missense Mutation (SNP) | VAF 354/946 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- JAM3 | c.94G>C p.V32L | Missense Mutation (SNP) | VAF 220/663 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MMP14 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 26/770 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NLRP9 | c.1281G>A p.M427I | Missense Mutation (SNP) | VAF 490/1239 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PLCB4 | c.3414del p.V1139Sfs*6 | Frame Shift Del (DEL) | VAF 210/818 reads (26%) | called by pindel, varscan2
- PON1 | c.553T>C p.Y185H | Missense Mutation (SNP) | VAF 36/1330 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RALGAPA1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 217/570 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPINT4 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 152/2240 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPON2 | c.473G>T p.S158I | Missense Mutation (SNP) | VAF 42/528 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SRRD | c.811-8C>A | Splice Region (SNP) | VAF 69/919 reads (8%) | called by muse, mutect2
- TIGD5 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 38/1087 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- TIMELESS | c.1045T>C p.F349L | Missense Mutation (SNP) | VAF 458/1537 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- USPL1 | c.2808G>T p.E936D | Missense Mutation (SNP) | VAF 74/1363 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2
- VPS37D | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 218/930 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF497 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 232/1412 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CCR9 | c.180C>T p.I60= (on ENST00000357632 / NM_031200.3; = p.I48= on NM_006641.4) | Silent (SNP) | VAF 457/1032 reads (44%) | catalogued as rs769563630; called by muse, mutect2, varscan2
- COL11A1 | c.412C>T p.L138= | Silent (SNP) | VAF 444/1026 reads (43%) | called by muse, mutect2, varscan2
- CXCR2 | c.924C>T p.C308= | Silent (SNP) | VAF 175/618 reads (28%) | catalogued as rs1559454365; called by muse, varscan2
- EDIL3 | c.60C>T p.F20= | Silent (SNP) | VAF 200/592 reads (34%) | called by muse, mutect2, varscan2
- FAT3 | c.11991G>A p.P3997= | Silent (SNP) | VAF 209/486 reads (43%) | catalogued as COSV53070778, COSV53133042; called by muse, mutect2, varscan2
- H3C4 | c.399G>T p.G133= | Silent (SNP) | VAF 80/847 reads (9%) | catalogued as COSV61911828; called by muse, mutect2
- HDAC9 | c.555G>A p.L185= | Silent (SNP) | VAF 60/984 reads (6%) | called by muse, mutect2
- ITGA4 | c.2100C>G p.V700= | Silent (SNP) | VAF 98/1330 reads (7%) | called by muse, mutect2
- KLK14 | c.162C>T p.G54= | Silent (SNP) | VAF 134/823 reads (16%) | catalogued as rs940437369; called by muse, mutect2, varscan2
- KRT82 | c.1026G>A p.L342= | Silent (SNP) | VAF 72/1197 reads (6%) | called by muse, mutect2
- PINK1 | c.852C>T p.S284= | Silent (SNP) | VAF 326/986 reads (33%) | catalogued as rs368453193; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM168 | c.1143T>C p.I381= | Silent (SNP) | VAF 234/953 reads (25%) | catalogued as COSV57181627; called by muse, mutect2, varscan2
- AASDHPPT | c.693+80G>A | Intron (SNP) | VAF 62/196 reads (32%) | catalogued as rs749934983; called by muse, mutect2, varscan2
- CCL3 | c.73+33T>C | Intron (SNP) | VAF 30/762 reads (4%) | called by muse, mutect2
- COL18A1 | c.3753+90C>A | Intron (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- FAM53A | c.883-2707C>T | Intron (SNP) | VAF 63/740 reads (9%) | catalogued as rs999488655; called by muse, mutect2
- FMNL3 | c.*2789G>A | 3'UTR (SNP) | VAF 242/1017 reads (24%) | catalogued as rs971148221; called by muse, mutect2, varscan2
- KPNA2 | c.667-8dup | Intron (INS) | VAF 177/516 reads (34%) | catalogued as rs199567873; called by mutect2, varscan2
- PFN1 | c.*24C>T | 3'UTR (SNP) | VAF 35/432 reads (8%) | catalogued as rs758578095; called by muse, mutect2
- PRKCA | c.*31G>T | 3'UTR (SNP) | VAF 188/510 reads (37%) | called by muse, mutect2, varscan2
- UQCR11 | c.*48G>A | 3'UTR (SNP) | VAF 59/355 reads (17%) | catalogued as rs759175910; called by muse, mutect2, varscan2
- USP17L2 | c.-4C>T | 5'UTR (SNP) | VAF 124/1764 reads (7%) | catalogued as rs1456157406; called by muse, mutect2
- ZG16B | c.82-27G>T | Intron (SNP) | VAF 34/142 reads (24%) | called by muse, mutect2, varscan2
